Surgical pathology report (de-identified scan), TCGA case TCGA-2X-A9D5, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site ABS IUPUI, specimen TCGA-2X-A9D5-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology Report

Taken: DOB: Gender: M

Operative Procedure:

Orchiectomy left

Pre-Operative Diagnosis:

Testicular mass

Specimen Received:

Left radical orchiectomy

Final Pathologic Diagnosis:

Testis, left, radical orchiectomy:

Histologic type: Seminoma (pure)

Tumor focality: Unifocal

Size

Main mass: 6.2 cm [greatest dimension]

Additional dimensions: 4.6 x 3.3 cm

Additional nodules: N/A

Macroscopic extent of tumor: Confined to testis

Microscopic extent of tumor:

Tunica vaginalis: Not involved

Spermatic cord: Not involved

Rete testis: Directly invaded by tumor

Scrotum: N/A

Lymph-vascular invasion: No

Intratubular germ cell neoplasia: Present

Surgical margin

Spermatic cord: Not involved

Other (specify): N/A

Other pathologic findings: None significant

Lymph nodes submitted: No

Pathologic stage (2010) pT1 pNX pM-N/A

The examination of this case material and the preparation of this report were performed by the staff pathologist.

Gross Description:

ICD-O-3

Seminoma NOS 9061/3

Site ④ Testis NOS C62.9

gn 3/3/14

[page 2 of 2]
Received in formalin, labeled "left radical orchiectomy" is a 95 g orchiectomy specimen, which consists of a 6.5 x 4.6 x 3.4 cm testicle with attached 5.3 x 1.0 x 0.6 cm epididymis, with attached 6.0 x 2.0 cm spermatic cord. The tunica vaginalis is tan-pink, smooth and glistening. Sectioning reveals a 6.2 x 4.6 x 3.3 cm tan, firm, lobulated, ill-defined predominately homogeneous mass which abuts the visceral layer of the tunica vaginalis. No extension outside the testicle is identified. The scant uninvolved testis is tan, soft and homogeneous. The seminiferous tubules string with ease. The spermatic cord on sectioning is unremarkable. A gross photograph is taken.

Representative sections are submitted as follows:

- 1 spermatic cord margin taken en face;
- 2 mass at Rete testis to include epididymis;
- 3 mass to epididymis;
- 4 mass to visceral layer of tunica vaginalis;
- 5 mass to uninvolved testicle;
- 6 proximal spermatic cord.

Microscopic Description:

The final diagnosis of each specimen incorporates the microscopic examination findings.

END OF REPORT

Criteria	6/12/17/13	Yes	No
Dual/Synchronous Primary	Noted		/

Source: NCI Genomic Data Commons file 5e4aede3-a270-4b92-b838-8f9c52798d8c (TCGA-2X-A9D5.5A0D7A7A-D5A4-4986-B231-D4B497208EB5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).